FM case AD1256 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/5250f605-720f-4069-bafc-c945b5281087

Male, 20.7 years: Neuroblastoma, NOS (ICD-O-3 9500/3) of the autonomic nervous system; metastasis biopsied or resected from the kidney. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Metastatic.
